Somatic mutation profile of tumor specimen TCGA-FP-A8CX-01A (aliquot TCGA-FP-A8CX-01A-11D-A364-08) from TCGA case TCGA-FP-A8CX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.2 years (22,000 days).
Specimen TCGA-FP-A8CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a00e87c1-13d4-45e5-a188-9cc79b21a601.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-A8CX-10A (Blood Derived Normal), aliquot TCGA-FP-A8CX-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a842c7d2-0cb6-4d28-a258-c62a2b91b51f

The open-access MAF lists 96 somatic variants for this specimen: 75 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, Intron 2, In Frame Del 2, Nonstop Mutation 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55731958; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- AC004997.1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.2); catalogued as rs1470134696, COSV53164198; called by muse, mutect2
- ADGRF3 | c.1190C>A p.P397Q (on ENST00000311519 / NM_001145168.1; = p.P198Q on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV100274655, COSV61049754; called by muse, mutect2, varscan2
- AMPH | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs1338903221, COSV100340408; called by muse, mutect2, varscan2
- ANK1 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1221629266, COSV55884088, COSV99227074; called by muse, mutect2, varscan2
- ARID4B | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1458092234, COSV99934779; called by muse, mutect2
- AZI2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs749360849, COSV55423732; called by muse, mutect2, varscan2
- C1S | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs147341600; called by muse, mutect2, varscan2
- CACNG3 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99135276; called by muse, mutect2, varscan2
- CCDC138 | c.1868A>G p.H623R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs201490835, COSV99718651; called by mutect2, varscan2
- CD1D | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100939518; called by muse, mutect2
- CD2 | c.184del p.T62Lfs*31 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs750577393; called by mutect2, pindel, varscan2
- CDH12 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV101200674; called by muse, mutect2, varscan2
- CEMP1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs767649302, COSV99565481; called by muse, mutect2
- CHD1L | c.338A>T p.E113V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100787269; called by muse, mutect2
- CHD9 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99528576; called by muse, mutect2, varscan2
- CNKSR3 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as COSV101401270; called by muse, mutect2, varscan2
- CRMP1 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100271172, COSV61478051; called by muse, mutect2, varscan2
- CSMD3 | c.3848C>A p.A1283D (on ENST00000297405 / NM_001363185.1; = p.A1179D on NM_052900.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52176973, COSV99820986; called by muse, varscan2
- DCST1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1329564286, COSV99792573; called by muse, mutect2
- DMD | c.6173A>C p.K2058T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.71); catalogued as COSV100817165, COSV63733580; called by muse, mutect2, varscan2
- DOCK2 | c.4912C>T p.R1638C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs771330901, COSV56984726; called by mutect2, varscan2
- EBF3 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV100799572, COSV62482301; called by muse, mutect2
- ERLEC1 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99482789; called by muse, mutect2
- ERVFRD-1 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100977331; called by muse, mutect2, varscan2
- FASTKD5 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV53910357; called by muse, mutect2
- FCRL5 | c.536A>T p.N179I | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100708387; called by muse, mutect2, varscan2
- FKBP9 | c.813_814del p.C271* | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | catalogued as rs1447111827; called by pindel, varscan2
- GABRA1 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV50098481, COSV99195673; called by muse, mutect2
- GCM2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV101069392; called by muse, mutect2, varscan2
- GLI3 | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV101229668; called by muse, mutect2
- GNAI1 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV63525003; called by muse, mutect2
- GYG2 | c.553C>A p.H185N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.884); catalogued as COSV100088546; called by muse, mutect2
- HAO2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs902535162, COSV100377680; called by muse, mutect2
- ITFG1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV100278213; called by muse, mutect2
- LMO3 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99662508; called by muse, mutect2, varscan2
- LRP12 | c.2034A>C p.K678N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99406995; called by muse, mutect2, varscan2
- MAGEB18 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100305243; called by muse, mutect2
- MLXIPL | c.1823-1G>C p.X608_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100515131; called by muse, mutect2
- MROH2B | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV101270429; called by muse, mutect2, varscan2
- NCBP2 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs780934944, COSV58317172; called by muse, mutect2, varscan2
- NCKAP5 | c.3745A>T p.R1249* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100489422; called by muse, mutect2
- NDNF | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101113065; called by muse, mutect2
- NELFCD | c.1576C>T p.R526* (on ENST00000602795; = p.R508* on NM_198976.4) | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | catalogued as rs1288162314, COSV53882585; called by muse, mutect2, varscan2
- NIPBL | c.3502+2T>C p.X1168_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as rs1428269028, COSV99238246; called by muse, mutect2, varscan2
- NLRP5 | c.225A>C p.E75D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV101173282; called by muse, mutect2, varscan2
- OR10J3 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV59953513, COSV59954079; called by muse, mutect2, varscan2
- OR13C8 | c.961T>G p.*321Gext*? | Nonstop Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100622895; called by muse, mutect2, varscan2
- OSBP | c.1991G>A p.G664D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as COSV99802498; called by muse, mutect2
- PCLO | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100426272, COSV61660317; called by muse, mutect2, varscan2
- PGAP1 | c.2737C>G p.L913V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100697938; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1259C>G p.P420R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV99241514; called by muse, mutect2, varscan2
- RB1CC1 | c.2113A>G p.I705V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99205022; called by muse, mutect2, varscan2
- SERTAD4 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.713); catalogued as COSV100882572; called by muse, mutect2
- SH3TC2 | c.3135G>T p.E1045D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100100963; called by muse, mutect2, varscan2
- SI | c.3659C>T p.A1220V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100013401; called by muse, mutect2, varscan2
- SLC12A3 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs201432183, COSV99343698; called by muse, mutect2, varscan2
- SLC12A7 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs780126009, COSV99369124; called by muse, mutect2, varscan2
- SLC2A9 | c.1075A>C p.S359R | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV99303515; called by muse, mutect2
- SLITRK2 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV59427207; called by muse, mutect2
- SNX18 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100410124; called by muse, varscan2
- STXBP5 | c.1582T>A p.Y528N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99468735; called by muse, mutect2, varscan2
- TAFA2 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101352637; called by muse, mutect2, varscan2
- TMTC3 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.431); catalogued as COSV57125487, COSV99897927; called by muse, mutect2, varscan2
- TRAF3IP3 | c.789G>T p.W263C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV99159952; called by muse, mutect2
- TSSK1B | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV101180906; called by muse, mutect2, varscan2
- UBTD1 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100080656; called by muse, mutect2, varscan2
- ATP6V0E1 | c.150_152+5del p.X50_splice | Splice Site (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- IGKV1-6 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- POLG | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SAP30BP | c.770_772del p.W257_D258delinsY | In Frame Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- SLC16A12 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TACC2 | c.2789_2790del p.E930Vfs*25 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2
- TPX2 | c.1654_1656del p.E552del | In Frame Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.14220A>T p.G4740= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV101315302; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4590A>G p.K1530= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs761263851, COSV99781749; called by muse, mutect2, varscan2
- CHST10 | c.741G>A p.P247= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs139681629; called by muse, mutect2, varscan2
- COL4A2 | c.753C>T p.N251= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs763026854, COSV64624841; called by muse, mutect2, varscan2
- CSMD3 | c.9996A>G p.Q3332= (on ENST00000297405 / NM_001363185.1; = p.Q3163= on NM_052900.3) | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV52177216, COSV99820985; called by muse, mutect2
- DCAF11 | c.15C>T p.N5= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100386545; called by muse, mutect2, varscan2
- DIAPH3 | c.199C>T p.L67= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs373421558; called by muse, mutect2, varscan2
- DNAH5 | c.12453C>T p.N4151= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs764777394, COSV54202654; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNMT3A | c.336C>T p.G112= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs779949977, COSV53057163, COSV99259419; called by muse, mutect2, varscan2
- FGF12 | c.564A>G p.R188= (on ENST00000454309 / NM_021032.5; = p.R126= on NM_004113.6) | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV99277938; called by muse, mutect2, varscan2
- HIRIP3 | c.843G>A p.Q281= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as rs754588606, COSV99662769; called by muse, mutect2
- IFNA6 | c.513C>A p.I171= | Silent (SNP) | VAF 34/293 reads (12%) | catalogued as COSV101207006; called by muse, mutect2, varscan2
- PRR16 | c.420G>T p.V140= (on ENST00000407149 / NM_001300783.2; = p.V117= on NM_016644.2) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101086061; called by muse, mutect2, varscan2
- RETREG2 | c.1614G>A p.Q538= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs928913084, COSV56088674; called by muse, mutect2
- RTL9 | c.2520C>A p.P840= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV101511598; called by muse, mutect2, varscan2
- SVIL | c.3846C>T p.G1282= (on ENST00000355867 / NM_021738.3; = p.G856= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV63443072; called by muse, mutect2
- TAS1R2 | c.2037C>T p.Y679= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs754222413, COSV100946109; called by muse, mutect2
- ATG16L1 | c.954+990C>T | Intron (SNP) | VAF 15/144 reads (10%) | catalogued as COSV100731219; called by muse, mutect2, varscan2
- CSMD3 | c.178+59896C>A | Intron (SNP) | VAF 10/83 reads (12%) | catalogued as rs941693073, COSV52103828, COSV99820987; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397579 C>A | 3'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- XIST | n.10041C>T | RNA (SNP) | VAF 7/22 reads (32%) | catalogued as rs1000108401; called by muse, mutect2, varscan2
